Somatic mutation profile of tumor specimen TARGET-10-PARDLP-09A (aliquot TARGET-10-PARDLP-09A-01D) from TARGET case TARGET-10-PARDLP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,621 days).
Specimen TARGET-10-PARDLP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67a57154-ecf8-4820-ac3c-33ce7845ec5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDLP-10A (Blood Derived Normal), aliquot TARGET-10-PARDLP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ff169ad-85ab-4ab1-8e73-b4e501798975

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP3 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1042827145; called by muse, mutect2, varscan2
- CALML5 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs368824145; called by muse, mutect2, varscan2
- CC2D1A | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV58783442; called by muse, mutect2, varscan2
- DLGAP4 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as rs376864546; called by muse, mutect2, varscan2
- INCENP | c.1753C>T p.R585C (on ENST00000394818 / NM_001040694.2; = p.R581C on NM_020238.3) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774422795; called by muse, mutect2, varscan2
- MAGED2 | c.909G>A p.S303= | Splice Region (SNP) | VAF 19/95 reads (20%) | catalogued as rs771039734; called by muse, mutect2, varscan2
- NCOR2 | c.4196C>T p.T1399M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.593); catalogued as rs115154917, COSV62300262; called by muse, varscan2
- PRR5-ARHGAP8 | c.862C>T p.R288C (on ENST00000352766; = p.R165C on NM_181334.5) | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs779829700; called by muse, mutect2, varscan2
- TUBAL3 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as rs782217301; called by muse, mutect2, varscan2
- CLCN5 | c.1950A>C p.K650N | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLT3 | c.1868A>T p.K623I | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MYRFL | c.2519G>A p.R840K | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.005); called by muse, mutect2
- PPIL2 | c.1311del p.Y438Mfs*18 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- CHRM1 | c.894C>T p.S298= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as rs777950025; called by muse, mutect2, varscan2
- IGSF5 | c.912T>C p.C304= | Silent (SNP) | VAF 27/93 reads (29%) | called by muse, mutect2, varscan2
- PTPN13 | c.2976A>G p.P992= | Silent (SNP) | VAF 49/142 reads (35%) | called by muse, mutect2, varscan2
- SEC31B | c.273C>T p.G91= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs760930588, COSV64824595; called by muse, mutect2, varscan2
- SETBP1 | c.582C>T p.D194= | Silent (SNP) | VAF 28/96 reads (29%) | called by muse, mutect2, varscan2
